Somatic mutation profile of tumor specimen C3L-07956-03 (aliquot CPT0450880006) from CPTAC case C3L-07956, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 78.0 years (28,484 days).
Specimen C3L-07956-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e42cf5c9-e831-402b-974a-ea9da7e33404.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07956-31 (Blood Derived Normal), aliquot CPT0451010004; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/10500caf-1a19-402b-bc41-0786dc8b9f71

The open-access MAF lists 287 somatic variants for this specimen: 189 protein-altering or splice-affecting, 85 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 170, Silent 85, Nonsense Mutation 12, Intron 7, Frame Shift Ins 3, 3'UTR 2, Frame Shift Del 2, Splice Site 1, 5'Flank 1, 3'Flank 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AQP2 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 87/573 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.122); catalogued as rs104894339, CM950083, COSV52229975; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.2077C>T p.R693* | Nonsense Mutation (SNP) | VAF 76/368 reads (21%) | hotspot (GDC flag); catalogued as COSV61375361; called by muse, mutect2, varscan2
- MAGEC1 | c.3138A>T p.K1046N | Missense Mutation (SNP) | VAF 98/288 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as COSV53569304, COSV53569381; called by muse, mutect2, varscan2
- PTEN | c.385G>A p.G129R | Missense Mutation (SNP) | VAF 65/388 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786204929, CM122894, COSV64288557, COSV64309376; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SCN5A | c.2440C>T p.R814W | Missense Mutation (SNP) | VAF 38/255 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs199473161, CM055530, COSV61129337, COSV61136044; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A4GNT | c.776G>T p.R259I | Missense Mutation (SNP) | VAF 73/404 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52628691, COSV52630057; called by muse, mutect2, varscan2
- ABCC11 | c.3962G>A p.R1321H | Missense Mutation (SNP) | VAF 74/423 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as rs762213795, COSV99077005; called by muse, mutect2, varscan2
- ADGRL4 | c.710C>T p.S237F | Missense Mutation (SNP) | VAF 42/302 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as COSV66061064; called by muse, mutect2, varscan2
- ANKMY1 | c.1048C>T p.R350W | Missense Mutation (SNP) | VAF 62/386 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs144393814; called by muse, varscan2
- ANO2 | c.1066dup p.I356Nfs*34 (on ENST00000356134 / NM_001278597.3; = p.I360Nfs*34 on NM_001278596.3) | Frame Shift Ins (INS) | VAF 38/278 reads (14%) | catalogued as rs1565640555; called by mutect2, pindel, varscan2
- ARHGEF7 | c.440C>T p.S147L (on ENST00000375741 / NM_001113511.2; = p.S126L on NM_145735.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/335 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.407); catalogued as rs750993031, COSV54541804, COSV54543563; called by muse, mutect2, varscan2
- ARNT | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 39/253 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs146813760, COSV62230286; called by muse, mutect2, varscan2
- BMPER | c.47G>A p.R16H | Missense Mutation (SNP) | VAF 96/420 reads (23%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.198); catalogued as rs866309179, COSV99780621; called by muse, mutect2, varscan2
- CAPN13 | c.1631G>A p.R544H | Missense Mutation (SNP) | VAF 51/331 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs745335171, COSV99700230; called by muse, varscan2
- CARD11 | c.1309C>T p.R437C | Missense Mutation (SNP) | VAF 69/399 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV67800282; called by muse, varscan2
- CCDC34 | c.633_636del p.N212Kfs*28 | Frame Shift Del (DEL) | VAF 31/217 reads (14%) | catalogued as rs760237558; called by mutect2, pindel, varscan2
- CLIP2 | c.2311C>T p.R771W | Missense Mutation (SNP) | VAF 90/485 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs750568179, COSV56278216; called by muse, varscan2
- COL6A3 | c.3274G>A p.V1092I | Missense Mutation (SNP) | VAF 81/415 reads (20%) | SIFT tolerated (0.85); PolyPhen benign (0.005); catalogued as rs576798969, COSV55085649; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A6 | c.3112C>T p.R1038* | Nonsense Mutation (SNP) | VAF 59/398 reads (15%) | catalogued as rs777444690, COSV62018197; called by muse, mutect2, varscan2
- CPN1 | c.712C>T p.R238C | Missense Mutation (SNP) | VAF 54/325 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as rs760356142, COSV64942879; called by muse, mutect2, varscan2
- CSMD3 | c.10061A>C p.N3354T (on ENST00000297405 / NM_001363185.1; = p.N3185T on NM_052900.3) | Missense Mutation (SNP) | VAF 48/306 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376050476, COSV52312561; called by muse, mutect2, varscan2
- DCAF4L2 | c.122A>G p.N41S | Missense Mutation (SNP) | VAF 77/415 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs150956115; called by muse, mutect2, varscan2
- DENND5B | c.3046G>C p.E1016Q | Missense Mutation (SNP) | VAF 52/274 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100172283; called by muse, mutect2, varscan2
- DENND6B | c.1496G>A p.R499Q | Missense Mutation (SNP) | VAF 57/413 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as rs754969072; called by muse, mutect2, varscan2
- DNTTIP2 | c.157G>A p.G53R | Missense Mutation (SNP) | VAF 59/368 reads (16%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV100785189; called by muse, mutect2, varscan2
- DOK7 | c.325G>A p.G109S | Missense Mutation (SNP) | VAF 35/357 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762952740, CM108748, COSV60773721; called by muse, mutect2, varscan2
- DZANK1 | c.1967C>T p.A656V (on ENST00000262547 / NM_001099407.1; = p.A463V on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/321 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs1313127515; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 51/367 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1166291611, COSV57514677; called by muse, mutect2, varscan2
- ELOA2 | c.1949C>T p.T650M | Missense Mutation (SNP) | VAF 82/488 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV99796262; called by muse, mutect2, varscan2
- EXD3 | c.113G>A p.R38Q | Missense Mutation (SNP) | VAF 51/303 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs763297297, COSV99049326; called by muse, mutect2, varscan2
- FANCI | c.2684C>T p.S895L (on ENST00000310775 / NM_001376911.1; = p.S835L on NM_018193.3) | Missense Mutation (SNP) | VAF 36/246 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs762647324; called by muse, mutect2, varscan2
- FAT3 | c.7628G>T p.R2543L | Missense Mutation (SNP) | VAF 49/437 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as rs1234031232, COSV53075769; called by muse, mutect2, varscan2
- FBXL6 | c.1178G>A p.G393D | Missense Mutation (SNP) | VAF 76/555 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1447039603; called by muse, mutect2, varscan2
- FBXL7 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 95/601 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.293); catalogued as rs766043354, COSV100310366, COSV61650035; called by muse, mutect2, varscan2
- FSTL5 | c.366dup p.Q123Tfs*9 | Frame Shift Ins (INS) | VAF 31/270 reads (11%) | catalogued as rs1293605811; called by mutect2, pindel, varscan2
- FZR1 | c.625G>A p.V209M | Missense Mutation (SNP) | VAF 77/378 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs967469604, COSV100553573; called by muse, mutect2, varscan2
- GJA10 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 75/491 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.089); catalogued as rs540684772; called by muse, mutect2, varscan2
- HERC2 | c.3629T>G p.I1210R | Missense Mutation (SNP) | VAF 55/336 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55352769; called by muse, mutect2, varscan2
- HOXD3 | c.1264C>T p.R422* | Nonsense Mutation (SNP) | VAF 76/424 reads (18%) | catalogued as COSV50880048; called by muse, varscan2
- HROB | c.1690G>A p.V564M | Missense Mutation (SNP) | VAF 48/312 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs200296668; called by muse, mutect2, varscan2
- HSPB3 | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 50/311 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757814001, COSV57356665; called by muse, mutect2, varscan2
- IL3 | c.392C>T p.T131M | Missense Mutation (SNP) | VAF 58/357 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as rs767113880; called by muse, mutect2, varscan2
- IL7R | c.999A>T p.E333D | Missense Mutation (SNP) | VAF 86/491 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.012); catalogued as COSV57408274, COSV57413927; called by muse, mutect2, varscan2
- ILDR2 | c.1687G>A p.A563T | Missense Mutation (SNP) | VAF 128/640 reads (20%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as rs1416379592; called by muse, mutect2, varscan2
- IMPG1 | c.1712G>T p.R571L | Missense Mutation (SNP) | VAF 58/325 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.576); catalogued as COSV64058960; called by muse, mutect2, varscan2
- IRX2 | c.1067C>T p.A356V | Missense Mutation (SNP) | VAF 125/661 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1349932792, COSV57411827; called by muse, mutect2, varscan2
- KCNA4 | c.508C>A p.R170S | Missense Mutation (SNP) | VAF 67/479 reads (14%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.026); catalogued as COSV100068652; called by muse, mutect2, varscan2
- KCNS3 | c.778T>C p.F260L | Missense Mutation (SNP) | VAF 74/469 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as rs532095670; called by muse, mutect2, varscan2
- KHDRBS3 | c.382C>T p.H128Y | Missense Mutation (SNP) | VAF 57/398 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs771409135, COSV63421094; called by muse, mutect2, varscan2
- KIAA1755 | c.1912G>A p.A638T | Missense Mutation (SNP) | VAF 118/474 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.324); catalogued as rs138150915; called by muse, mutect2, varscan2
- KIF19 | c.1337G>A p.R446H | Missense Mutation (SNP) | VAF 75/496 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs753560033, COSV100739015; called by muse, mutect2, varscan2
- KIF27 | c.1664T>G p.L555R | Missense Mutation (SNP) | VAF 67/319 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV52825178; called by muse, mutect2, varscan2
- LRRC4C | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 63/307 reads (21%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.177); catalogued as COSV99537812; called by muse, mutect2, varscan2
- MBD5 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 60/313 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs772364272, COSV101289867; called by muse, mutect2, varscan2
- MCHR2 | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 40/235 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV56001528; called by muse, mutect2, varscan2
- MEF2C | c.1255T>A p.S419T | Missense Mutation (SNP) | VAF 52/540 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100424708; called by muse, mutect2
- MEGF6 | c.3670G>T p.G1224W | Missense Mutation (SNP) | VAF 103/520 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs865833922; called by muse, mutect2, varscan2
- MEOX1 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 96/561 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.386); catalogued as rs140721400; called by muse, mutect2, varscan2
- MYH8 | c.2017G>A p.V673I | Missense Mutation (SNP) | VAF 40/282 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs142181278; called by muse, varscan2
- NALCN | c.3109C>T p.Q1037* | Nonsense Mutation (SNP) | VAF 53/302 reads (18%) | catalogued as rs572483914, COSV51972182; called by muse, mutect2, varscan2
- NCAN | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 84/443 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs1396995508, COSV53046925; called by muse, mutect2, varscan2
- NUP54 | c.1381C>T p.R461* | Nonsense Mutation (SNP) | VAF 31/247 reads (13%) | catalogued as rs377634247; called by muse, mutect2, varscan2
- OR1B1 | c.355G>T p.V119F | Missense Mutation (SNP) | VAF 90/464 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100506548, COSV59172239; called by muse, mutect2
- OR5R1 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 68/385 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs771782696, COSV56571910; called by mutect2, varscan2
- OTOGL | c.4723G>T p.E1575* (on ENST00000547103; = p.E1566* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 30/205 reads (15%) | catalogued as COSV54014641; called by muse, mutect2, varscan2
- PCLO | c.14672G>A p.R4891H | Missense Mutation (SNP) | VAF 55/443 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376928297; called by muse, mutect2, varscan2
- PFDN5 | c.391G>A p.V131I | Missense Mutation (SNP) | VAF 45/211 reads (21%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.561); catalogued as rs1032296138, COSV54476932; called by muse, mutect2, varscan2
- PHIP | c.3929G>A p.R1310H | Missense Mutation (SNP) | VAF 56/285 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs909398575, COSV51507022; called by muse, mutect2, varscan2
- PIK3CB | c.1654G>A p.E552K | Missense Mutation (SNP) | VAF 54/301 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100006173, COSV56683125, COSV56690507; called by muse, mutect2, varscan2
- POU6F2 | c.1763G>A p.R588H | Missense Mutation (SNP) | VAF 86/587 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as rs560129989; called by muse, mutect2, varscan2
- PRDM15 | c.2353G>A p.A785T | Missense Mutation (SNP) | VAF 38/235 reads (16%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.557); catalogued as rs753342130, COSV99519432; called by muse, mutect2, varscan2
- PRKCA | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 51/329 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.047); catalogued as rs758445868, COSV52582160; called by muse, mutect2, varscan2
- QSOX1 | c.1348C>T p.R450* | Nonsense Mutation (SNP) | VAF 88/496 reads (18%) | catalogued as rs1422113978; called by muse, varscan2
- RBL1 | c.2761G>A p.G921R | Missense Mutation (SNP) | VAF 82/353 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.493); catalogued as rs1340242413; called by muse, mutect2, varscan2
- REG1B | c.5C>G p.A2G | Missense Mutation (SNP) | VAF 29/334 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.305); catalogued as rs1434172745; called by muse, mutect2
- SEMA6A | c.1831G>T p.D611Y | Missense Mutation (SNP) | VAF 61/347 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.077); catalogued as COSV56714836; called by muse, mutect2, varscan2
- SIM2 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 83/478 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.696); catalogued as rs1485336653; called by muse, mutect2
- SLC10A2 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 52/287 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs148415870, COSV55359465; called by muse, mutect2, varscan2
- SLC27A1 | c.1834C>T p.R612C | Missense Mutation (SNP) | VAF 67/484 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs149575978; called by muse, mutect2, varscan2
- SLCO2B1 | c.260C>T p.S87L | Missense Mutation (SNP) | VAF 44/395 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs1282514172; called by muse, mutect2, varscan2
- SLITRK3 | c.1328G>A p.R443H | Missense Mutation (SNP) | VAF 77/499 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs773404533, COSV53849824; called by muse, mutect2, varscan2
- SNX13 | c.1827C>A p.H609Q | Missense Mutation (SNP) | VAF 56/314 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV101296872; called by muse, mutect2, varscan2
- SPATA31E1 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 34/344 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as rs557708519; called by muse, mutect2, varscan2
- SPRTN | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 43/247 reads (17%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs762108108, COSV50477971; called by muse, mutect2, varscan2
- SPTBN5 | c.4097G>A p.R1366H | Missense Mutation (SNP) | VAF 66/411 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.012); catalogued as rs747726960, COSV100311373; called by muse, mutect2, varscan2
- STAB2 | c.5303T>C p.V1768A | Missense Mutation (SNP) | VAF 42/292 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as rs764737090; called by muse, mutect2, varscan2
- STMND1 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 72/485 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.229); catalogued as rs1301299694; called by muse, mutect2, varscan2
- STOML3 | c.353T>G p.V118G | Missense Mutation (SNP) | VAF 40/282 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65512179; called by muse, mutect2, varscan2
- SYNE1 | c.25656C>G p.C8552W (on ENST00000367255 / NM_182961.4; = p.C8504W on NM_033071.3) | Missense Mutation (SNP) | VAF 55/370 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54917777; called by muse, mutect2, varscan2
- TFEB | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 117/713 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as rs779275045, COSV57826701; called by muse, mutect2, varscan2
- TMEM108 | c.517C>T p.R173* | Nonsense Mutation (SNP) | VAF 92/452 reads (20%) | catalogued as rs1381522961; called by muse, mutect2, varscan2
- TRPS1 | c.1000C>T p.R334C (on ENST00000220888 / NM_001330599.2; = p.R347C on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/428 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs780212915, COSV55251565, COSV55256742; called by muse, mutect2, varscan2
- TTC29 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 43/227 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as rs753782633, COSV57272732; called by muse, mutect2, varscan2
- TTN | c.39892+1G>A p.X13298_splice (on ENST00000591111; = p.X5874_splice on NM_003319.4) | Splice Site (SNP) | VAF 36/209 reads (17%) | catalogued as COSV60201655; called by muse, mutect2, varscan2
- WDFY4 | c.5716C>T p.P1906S | Missense Mutation (SNP) | VAF 48/291 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as rs760694340; called by muse, mutect2, varscan2
- WDR97 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 144/742 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as rs1199786933; called by muse, mutect2, varscan2
- ZBTB2 | c.1477G>A p.V493I | Missense Mutation (SNP) | VAF 58/333 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs754997786; called by muse, mutect2, varscan2
- ZFHX4 | c.5930C>T p.A1977V | Missense Mutation (SNP) | VAF 38/596 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.062); catalogued as rs533318616, COSV50548006; called by muse, mutect2
- ZNF100 | c.898C>T p.R300W | Missense Mutation (SNP) | VAF 49/453 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.013); catalogued as rs558325819, COSV59746422; called by muse, mutect2, varscan2
- ZNF317 | c.485G>A p.G162E | Missense Mutation (SNP) | VAF 51/282 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0.01); catalogued as rs1455762618; called by muse, mutect2, varscan2
- ZNF732 | c.1378T>C p.Y460H | Missense Mutation (SNP) | VAF 98/508 reads (19%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs782392167; called by muse, mutect2, varscan2
- ZNF837 | c.1529G>A p.R510H | Missense Mutation (SNP) | VAF 108/580 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs762568181, COSV101418223; called by muse, mutect2, varscan2
- ABRAXAS1 | c.1026A>C p.Q342H | Missense Mutation (SNP) | VAF 72/436 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2
- AFF3 | c.1724C>T p.A575V | Missense Mutation (SNP) | VAF 118/710 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AKAP6 | c.6392A>T p.E2131V | Missense Mutation (SNP) | VAF 80/410 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- AMIGO3 | c.1337G>A p.R446H | Missense Mutation (SNP) | VAF 105/649 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.44); called by muse, mutect2, varscan2
- AQP9 | c.364G>A p.G122S | Missense Mutation (SNP) | VAF 61/293 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- ASB15 | c.559C>A p.Q187K | Missense Mutation (SNP) | VAF 82/435 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- BRINP3 | c.1092A>C p.Q364H | Missense Mutation (SNP) | VAF 58/382 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- C4orf54 | c.2372C>A p.S791Y | Missense Mutation (SNP) | VAF 118/546 reads (22%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- CBX6 | c.866A>G p.D289G | Missense Mutation (SNP) | VAF 131/682 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.035); called by mutect2, varscan2
- CCDC105 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 119/672 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- CCDC141 | c.500T>C p.L167P | Missense Mutation (SNP) | VAF 34/248 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CCDC168 | c.16898G>C p.S5633T | Missense Mutation (SNP) | VAF 85/435 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- CEACAM21 | c.565A>T p.R189W | Missense Mutation (SNP) | VAF 94/534 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- CFAP54 | c.3569C>A p.S1190* | Nonsense Mutation (SNP) | VAF 39/228 reads (17%) | called by mutect2, varscan2
- CHD7 | c.3645G>C p.K1215N | Missense Mutation (SNP) | VAF 63/408 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- CIZ1 | c.701G>T p.C234F | Missense Mutation (SNP) | VAF 43/288 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CPA2 | c.770G>T p.W257L | Missense Mutation (SNP) | VAF 44/288 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CTIF | c.1373A>G p.K458R | Missense Mutation (SNP) | VAF 64/389 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- DOCK10 | c.5293A>G p.T1765A | Missense Mutation (SNP) | VAF 69/312 reads (22%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- DONSON | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 123/699 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- DSCAM | c.5602A>T p.I1868F | Missense Mutation (SNP) | VAF 71/448 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DTD1 | c.170A>G p.D57G | Missense Mutation (SNP) | VAF 60/457 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- DVL2 | c.143A>G p.Q48R | Missense Mutation (SNP) | VAF 79/449 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- ERCC6L | c.1838_1841del p.K613Tfs*11 | Frame Shift Del (DEL) | VAF 62/234 reads (26%) | called by mutect2, pindel, varscan2
- ETFDH | c.1013G>C p.R338T | Missense Mutation (SNP) | VAF 50/329 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- FSD1L | c.1133C>T p.T378I | Missense Mutation (SNP) | VAF 32/241 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- FUBP1 | c.965T>C p.I322T | Missense Mutation (SNP) | VAF 47/271 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- FXR1 | c.591G>A p.M197I | Missense Mutation (SNP) | VAF 44/313 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- GABRB3 | c.964C>A p.L322M | Missense Mutation (SNP) | VAF 60/418 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- GCM2 | c.400A>T p.S134C | Missense Mutation (SNP) | VAF 52/350 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR6 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 93/607 reads (15%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- GRIK3 | c.2497G>A p.V833I | Missense Mutation (SNP) | VAF 109/563 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- GRIP1 | c.512A>G p.H171R | Missense Mutation (SNP) | VAF 38/294 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- HELLS | c.148G>T p.E50* | Nonsense Mutation (SNP) | VAF 39/267 reads (15%) | called by muse, mutect2, varscan2
- HEPHL1 | c.3448C>A p.Q1150K | Missense Mutation (SNP) | VAF 48/291 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- IGHM | c.1292A>G p.K431R | Missense Mutation (SNP) | VAF 46/300 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- ITPKA | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 73/393 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KLF13 | c.304G>T p.A102S | Missense Mutation (SNP) | VAF 55/230 reads (24%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRIT1 | c.599G>T p.G200V | Missense Mutation (SNP) | VAF 44/332 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- KRTAP19-7 | c.137A>T p.Y46F | Missense Mutation (SNP) | VAF 66/339 reads (19%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- LRFN5 | c.1202C>A p.T401N | Missense Mutation (SNP) | VAF 37/323 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- LRRC43 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 85/538 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- LTN1 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 38/191 reads (20%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.475); called by muse, varscan2
- MAP2 | c.1277T>C p.F426S | Missense Mutation (SNP) | VAF 75/406 reads (18%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO6 | c.3049G>T p.A1017S | Missense Mutation (SNP) | VAF 54/394 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- NCOA3 | c.1827A>T p.Q609H | Missense Mutation (SNP) | VAF 143/437 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- OLIG1 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 88/591 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- OR13H1 | c.238dup p.Q80Pfs*42 | Frame Shift Ins (INS) | VAF 99/310 reads (32%) | called by mutect2, pindel, varscan2
- OR2AG1 | c.317C>A p.T106K | Missense Mutation (SNP) | VAF 67/414 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- PANX3 | c.1018C>A p.L340I | Missense Mutation (SNP) | VAF 56/344 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- PCDH17 | c.3353T>G p.L1118R | Missense Mutation (SNP) | VAF 94/513 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PCDHB13 | c.229C>A p.Q77K | Missense Mutation (SNP) | VAF 31/319 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- PCDHGA1 | c.510C>A p.Y170* | Nonsense Mutation (SNP) | VAF 58/362 reads (16%) | called by muse, mutect2, varscan2
- PCLO | c.4510A>G p.T1504A | Missense Mutation (SNP) | VAF 81/443 reads (18%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PEPD | c.549C>T p.C183= | Splice Region (SNP) | VAF 45/277 reads (16%) | called by muse, mutect2, varscan2
- PHOSPHO1 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 110/628 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- PIWIL2 | c.2092G>T p.V698F | Missense Mutation (SNP) | VAF 44/210 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PLEC | c.8795G>C p.G2932A (on ENST00000322810 / NM_201380.4; = p.G2822A on NM_000445.5) | Missense Mutation (SNP) | VAF 133/869 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PLXDC1 | c.1105C>T p.P369S | Missense Mutation (SNP) | VAF 86/486 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- POLRMT | c.1148G>A p.R383H | Missense Mutation (SNP) | VAF 35/290 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- POU3F1 | c.709G>A p.G237S | Missense Mutation (SNP) | VAF 102/583 reads (17%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- PYROXD1 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- RBBP6 | c.5177G>A p.S1726N | Missense Mutation (SNP) | VAF 84/449 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); called by mutect2, varscan2
- RBM17 | c.523A>G p.I175V | Missense Mutation (SNP) | VAF 53/343 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RBM46 | c.1139C>A p.P380Q | Missense Mutation (SNP) | VAF 45/342 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- RBSN | c.1771C>T p.L591F | Missense Mutation (SNP) | VAF 71/528 reads (13%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.44); called by muse, mutect2, varscan2
- SCEL | c.1879C>T p.P627S (on ENST00000349847 / NM_144777.3; = p.P607S on NM_003843.4) | Missense Mutation (SNP) | VAF 33/235 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SCNN1G | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 82/470 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- SEMA6D | c.2345A>G p.Q782R (on ENST00000316364 / NM_153618.2; = p.Q720R on NM_020858.2) | Missense Mutation (SNP) | VAF 96/495 reads (19%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- SFRP4 | c.214G>A p.V72M | Missense Mutation (SNP) | VAF 90/528 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- SGSM1 | c.1354C>T p.P452S | Missense Mutation (SNP) | VAF 87/545 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SLC12A9 | c.2023C>T p.P675S | Missense Mutation (SNP) | VAF 76/546 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SLC16A13 | c.1169C>A p.T390N | Missense Mutation (SNP) | VAF 94/466 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- STXBP5L | c.395A>C p.D132A | Missense Mutation (SNP) | VAF 39/284 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TCTEX1D4 | c.184T>G p.S62A | Missense Mutation (SNP) | VAF 110/702 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- TNC | c.4612T>C p.S1538P | Missense Mutation (SNP) | VAF 67/360 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- TPO | c.425G>T p.C142F | Missense Mutation (SNP) | VAF 61/401 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRPS1 | c.3650G>A p.C1217Y (on ENST00000220888 / NM_001330599.2; = p.C1230Y on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 85/607 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TTN | c.84842A>C p.K28281T (on ENST00000591111; = p.K20857T on NM_003319.4) | Missense Mutation (SNP) | VAF 59/431 reads (14%) | PolyPhen benign (0.027); called by muse, mutect2, varscan2
- TUBA8 | c.101G>A p.G34D | Missense Mutation (SNP) | VAF 60/358 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TYR | c.1558G>T p.D520Y | Missense Mutation (SNP) | VAF 32/246 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- USB1 | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 60/323 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- ZFP2 | c.679A>T p.M227L | Missense Mutation (SNP) | VAF 63/411 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ZGRF1 | c.5930C>T p.A1977V | Missense Mutation (SNP) | VAF 50/328 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- ZIM3 | c.119A>C p.N40T | Missense Mutation (SNP) | VAF 44/298 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.033); called by muse, mutect2
- ZNF469 | c.1344C>G p.Y448* | Nonsense Mutation (SNP) | VAF 116/559 reads (21%) | called by muse, mutect2, varscan2
- ZNF804A | c.1110A>G p.I370M | Missense Mutation (SNP) | VAF 54/363 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AARD | c.99G>A p.A33= | Silent (SNP) | VAF 96/613 reads (16%) | catalogued as COSV65600402; called by muse, mutect2, varscan2
- ACOT1 | c.732C>T p.F244= | Silent (SNP) | VAF 117/494 reads (24%) | called by muse, mutect2, varscan2
- ADAMTSL1 | c.1287G>A p.A429= | Silent (SNP) | VAF 77/439 reads (18%) | catalogued as rs771115371; called by muse, mutect2, varscan2
- ADGRB1 | c.675G>A p.A225= | Silent (SNP) | VAF 28/1014 reads (3%) | catalogued as rs1395449353; called by muse, mutect2
- AIM2 | c.510A>G p.Q170= | Silent (SNP) | VAF 63/387 reads (16%) | catalogued as rs757503647; called by muse, varscan2
- AKIP1 | c.237C>T p.P79= | Silent (SNP) | VAF 38/258 reads (15%) | called by muse, mutect2, varscan2
- ARHGEF5 | c.4650C>T p.G1550= | Silent (SNP) | VAF 43/285 reads (15%) | catalogued as rs769617324, COSV50209569; called by muse, mutect2, varscan2
- ASCL1 | c.543C>T p.S181= | Silent (SNP) | VAF 94/536 reads (18%) | catalogued as COSV57151901; called by muse, mutect2, varscan2
- C4orf54 | c.4689G>A p.P1563= | Silent (SNP) | VAF 63/409 reads (15%) | catalogued as rs1005727027, COSV72766786; called by muse, mutect2, varscan2
- CCNE1 | c.312G>A p.P104= | Silent (SNP) | VAF 54/362 reads (15%) | catalogued as rs200655498; called by muse, mutect2, varscan2
- CD7 | c.333C>T p.T111= | Silent (SNP) | VAF 104/546 reads (19%) | catalogued as COSV99486428; called by muse, mutect2, varscan2
- CDH10 | c.27G>T p.L9= | Silent (SNP) | VAF 39/286 reads (14%) | called by muse, mutect2, varscan2
- CDH9 | c.24A>G p.P8= | Silent (SNP) | VAF 29/221 reads (13%) | catalogued as rs773597398, COSV50327776; called by muse, mutect2, varscan2
- CES1 | c.756T>G p.T252= | Silent (SNP) | VAF 18/138 reads (13%) | called by mutect2, varscan2
- CLIP2 | c.1557C>T p.I519= | Silent (SNP) | VAF 94/543 reads (17%) | catalogued as rs370849725, COSV56276097; called by muse, mutect2, varscan2
- COG4 | c.1965G>A p.Q655= | Silent (SNP) | VAF 68/337 reads (20%) | called by muse, mutect2, varscan2
- COL14A1 | c.3729T>C p.F1243= | Silent (SNP) | VAF 42/362 reads (12%) | called by muse, varscan2
- CPM | c.234C>T p.Y78= | Silent (SNP) | VAF 72/333 reads (22%) | catalogued as rs758125830; called by muse, mutect2, varscan2
- DLL3 | c.1185C>T p.C395= | Silent (SNP) | VAF 106/533 reads (20%) | catalogued as rs778676863; called by muse, mutect2, varscan2
- DST | c.19216C>T p.L6406= (on ENST00000361203 / NM_001374722.1; = p.L4103= on NM_015548.5) | Silent (SNP) | VAF 75/341 reads (22%) | called by muse, mutect2, varscan2
- EMILIN1 | c.966G>T p.R322= | Silent (SNP) | VAF 111/631 reads (18%) | called by muse, mutect2, varscan2
- FAM120C | c.3024A>G p.K1008= | Silent (SNP) | VAF 40/173 reads (23%) | called by muse, mutect2, varscan2
- FBLN1 | c.117C>T p.D39= | Silent (SNP) | VAF 62/384 reads (16%) | catalogued as rs140917420; called by muse, varscan2
- FIGNL2 | c.588C>T p.Y196= | Silent (SNP) | VAF 85/580 reads (15%) | called by muse, varscan2
- GAB4 | c.1482G>A p.P494= | Silent (SNP) | VAF 47/269 reads (17%) | catalogued as rs142725655, COSV101271852; called by muse, mutect2, varscan2
- GATA3 | c.1282C>T p.L428= | Silent (SNP) | VAF 92/488 reads (19%) | catalogued as rs201681929, COSV104414171; called by muse, mutect2, varscan2
- GON4L | c.6267C>T p.D2089= | Silent (SNP) | VAF 67/483 reads (14%) | catalogued as rs1186769971; called by muse, mutect2, varscan2
- GRXCR1 | c.558C>T p.D186= | Silent (SNP) | VAF 68/399 reads (17%) | catalogued as rs367885687; called by muse, mutect2, varscan2
- HAS2 | c.918C>A p.G306= | Silent (SNP) | VAF 77/522 reads (15%) | called by muse, mutect2, varscan2
- IGFBP7 | c.279G>A p.R93= | Silent (SNP) | VAF 82/577 reads (14%) | called by muse, mutect2, varscan2
- IL26 | c.462T>C p.S154= | Silent (SNP) | VAF 35/269 reads (13%) | called by muse, mutect2, varscan2
- ITGA8 | c.1647G>A p.Q549= | Silent (SNP) | VAF 51/288 reads (18%) | catalogued as rs763059219, COSV65226969, COSV65228210; called by muse, mutect2, varscan2
- ITIH1 | c.2055C>T p.T685= | Silent (SNP) | VAF 69/390 reads (18%) | catalogued as COSV56259169; called by muse, mutect2, varscan2
- JHY | c.897G>A p.T299= | Silent (SNP) | VAF 64/288 reads (22%) | catalogued as rs376280199; called by muse, mutect2, varscan2
- KCNG2 | c.891C>T p.Y297= | Silent (SNP) | VAF 142/746 reads (19%) | catalogued as rs770063163; called by muse, mutect2, varscan2
- KCNS1 | c.504C>T p.D168= | Silent (SNP) | VAF 108/795 reads (14%) | called by muse, mutect2, varscan2
- KDM4B | c.2967C>T p.D989= | Silent (SNP) | VAF 64/380 reads (17%) | catalogued as rs749397162; called by muse, mutect2, varscan2
- KRTAP13-3 | c.273T>G p.S91= | Silent (SNP) | VAF 82/507 reads (16%) | catalogued as COSV61879462, COSV61879897, COSV61880010; called by muse, mutect2, varscan2
- LAMC1 | c.3417G>A p.E1139= | Silent (SNP) | VAF 74/421 reads (18%) | called by muse, mutect2, varscan2
- LIPT1 | c.582G>A p.K194= | Silent (SNP) | VAF 69/397 reads (17%) | called by muse, mutect2, varscan2
- MCM8 | c.669G>A p.G223= | Silent (SNP) | VAF 143/483 reads (30%) | catalogued as rs753297297, COSV99495438; called by muse, mutect2, varscan2
- MEF2C | c.1014C>T p.T338= | Silent (SNP) | VAF 68/341 reads (20%) | catalogued as rs1404943567; called by muse, mutect2, varscan2
- MGAT4D | c.456G>A p.L152= | Silent (SNP) | VAF 41/346 reads (12%) | called by muse, mutect2, varscan2
- MYO19 | c.1839G>A p.T613= | Silent (SNP) | VAF 87/487 reads (18%) | catalogued as rs765074076; called by muse, mutect2, varscan2
- NLRP6 | c.879G>T p.A293= | Silent (SNP) | VAF 113/678 reads (17%) | called by muse, mutect2, varscan2
- NXPE2 | c.1431C>T p.F477= | Silent (SNP) | VAF 84/350 reads (24%) | called by muse, mutect2, varscan2
- OBSL1 | c.3891G>A p.G1297= | Silent (SNP) | VAF 90/642 reads (14%) | catalogued as rs1266636610; called by muse, mutect2, varscan2
- OR11H12 | c.45T>C p.S15= | Silent (SNP) | VAF 64/435 reads (15%) | called by muse, mutect2, varscan2
- OR1R1P | c.537C>T p.C179= | Silent (SNP) | VAF 64/387 reads (17%) | called by muse, mutect2, varscan2
- OR4A8 | c.495T>G p.P165= | Silent (SNP) | VAF 45/317 reads (14%) | called by muse, mutect2, varscan2
- OR8B2 | c.165C>A p.L55= | Silent (SNP) | VAF 45/451 reads (10%) | called by muse, varscan2
- P2RY8 | c.669G>A p.T223= | Silent (SNP) | VAF 146/655 reads (22%) | catalogued as rs370852351, COSV101183981; called by muse, mutect2, varscan2
- PCDHA10 | c.1647G>A p.T549= | Silent (SNP) | VAF 96/575 reads (17%) | catalogued as COSV56493405; called by muse, mutect2, varscan2
- PCDHGB1 | c.1815G>T p.L605= | Silent (SNP) | VAF 51/507 reads (10%) | called by muse, mutect2, varscan2
- PHF2 | c.2526C>A p.G842= | Silent (SNP) | VAF 98/516 reads (19%) | called by mutect2, varscan2
- PLA2G4D | c.93G>A p.A31= | Silent (SNP) | VAF 47/320 reads (15%) | catalogued as rs367582020; called by muse, mutect2, varscan2
- POU3F2 | c.471C>T p.H157= | Silent (SNP) | VAF 121/682 reads (18%) | catalogued as rs748832920; called by muse, mutect2, varscan2
- POU4F1 | c.375C>T p.L125= | Silent (SNP) | VAF 22/194 reads (11%) | called by muse, varscan2
- PRKG1 | c.1728A>C p.P576= | Silent (SNP) | VAF 53/249 reads (21%) | called by muse, mutect2, varscan2
- PRR33 | c.1326C>T p.N442= | Silent (SNP) | VAF 95/613 reads (15%) | catalogued as rs750539867; called by muse, mutect2, varscan2
- PRSS12 | c.975C>A p.G325= | Silent (SNP) | VAF 29/227 reads (13%) | called by muse, mutect2, varscan2
- PTF1A | c.471C>T p.S157= | Silent (SNP) | VAF 39/265 reads (15%) | catalogued as rs1198700108; called by muse, mutect2, varscan2
- QSER1 | c.2688C>T p.V896= (on ENST00000399302; = p.V1025= on NM_001076786.3) | Silent (SNP) | VAF 64/436 reads (15%) | called by muse, mutect2, varscan2
- RADIL | c.588G>A p.P196= | Silent (SNP) | VAF 107/559 reads (19%) | catalogued as rs767893967; called by muse, mutect2, varscan2
- RANBP6 | c.2865T>A p.A955= | Silent (SNP) | VAF 55/372 reads (15%) | called by muse, mutect2, varscan2
- RIN3 | c.2796C>T p.F932= | Silent (SNP) | VAF 148/766 reads (19%) | called by muse, mutect2, varscan2
- RNASEH2A | c.450G>A p.Q150= | Silent (SNP) | VAF 71/385 reads (18%) | catalogued as rs1050699334; called by muse, mutect2, varscan2
- ROBO2 | c.2106G>A p.L702= | Silent (SNP) | VAF 58/379 reads (15%) | called by muse, mutect2, varscan2
- SEMA3D | c.447A>G p.G149= | Silent (SNP) | VAF 42/277 reads (15%) | called by muse, mutect2, varscan2
- SEPTIN5 | c.72C>T p.Y24= | Silent (SNP) | VAF 57/288 reads (20%) | catalogued as rs754793103, COSV63530788; called by muse, mutect2, varscan2
- SH2B2 | c.756C>T p.A252= | Silent (SNP) | VAF 115/680 reads (17%) | catalogued as COSV60825734; called by muse, mutect2, varscan2
- SLC25A24 | c.771C>T p.N257= | Silent (SNP) | VAF 68/370 reads (18%) | catalogued as rs150730278; called by muse, mutect2, varscan2
- SLC5A5 | c.186G>A p.S62= | Silent (SNP) | VAF 124/630 reads (20%) | called by muse, mutect2, varscan2
- SORCS3 | c.2607C>T p.Y869= | Silent (SNP) | VAF 57/419 reads (14%) | catalogued as rs527874475, COSV63794676; called by muse, mutect2, varscan2
- SPSB4 | c.165G>A p.A55= | Silent (SNP) | VAF 100/582 reads (17%) | catalogued as rs760295952, COSV100141021; called by muse, varscan2
- SYNE1 | c.6165A>G p.E2055= (on ENST00000367255 / NM_182961.4; = p.E2062= on NM_033071.3) | Silent (SNP) | VAF 55/373 reads (15%) | catalogued as COSV54919898, COSV54925449; called by muse, varscan2
- TAGLN3 | c.516C>T p.N172= | Silent (SNP) | VAF 61/392 reads (16%) | catalogued as rs759725437, COSV56328546; called by muse, mutect2, varscan2
- TARS3 | c.1377T>C p.S459= | Silent (SNP) | VAF 71/376 reads (19%) | catalogued as rs973608777; called by muse, mutect2, varscan2
- TLR4 | c.583T>C p.L195= (on ENST00000355622 / NM_138554.5; = p.L155= on NM_003266.4) | Silent (SNP) | VAF 70/427 reads (16%) | catalogued as COSV100790653, COSV100790676, COSV62922341; called by muse, mutect2, varscan2
- TMPRSS11B | c.267T>C p.S89= | Silent (SNP) | VAF 41/270 reads (15%) | called by muse, mutect2, varscan2
- UNCX | c.1029G>A p.P343= | Silent (SNP) | VAF 122/606 reads (20%) | called by muse, varscan2
- UVRAG | c.1278C>A p.V426= | Silent (SNP) | VAF 26/258 reads (10%) | called by muse, mutect2, varscan2
- VPS13B | c.8916A>C p.S2972= | Silent (SNP) | VAF 56/460 reads (12%) | called by muse, mutect2, varscan2
- ZNF687 | c.3423C>T p.G1141= | Silent (SNP) | VAF 100/571 reads (18%) | called by muse, mutect2, varscan2
- ZNF99 | c.1446A>G p.K482= | Silent (SNP) | VAF 52/390 reads (13%) | called by muse, mutect2, varscan2
- C5orf38 | c.*177G>A | 3'UTR (SNP) | VAF 126/714 reads (18%) | catalogued as rs750882907; called by muse, mutect2, varscan2
- C9orf129 | n.661C>T | RNA (SNP) | VAF 94/560 reads (17%) | catalogued as rs1319315780; called by muse, mutect2, varscan2
- CSNK1E | c.885+2113C>T | Intron (SNP) | VAF 56/350 reads (16%) | called by muse, mutect2, varscan2
- CSNK1G1 | c.1108-8016C>T | Intron (SNP) | VAF 56/317 reads (18%) | catalogued as rs562325646; called by muse, mutect2, varscan2
- EYS | c.1766+2564A>C | Intron (SNP) | VAF 30/197 reads (15%) | catalogued as COSV100677181; called by muse, mutect2, varscan2
- IQCF6 | chr3:51779217 G>C | 5'Flank (SNP) | VAF 52/400 reads (13%) | called by muse, mutect2, varscan2
- MASP1 | c.1303+5537G>A | Intron (SNP) | VAF 89/544 reads (16%) | catalogued as rs765808321, COSV56225339; called by muse, mutect2, varscan2
- OR8G5 | c.-1A>G | 5'UTR (SNP) | VAF 53/386 reads (14%) | called by muse, mutect2, varscan2
- SH3PXD2B | c.*2689C>T | 3'UTR (SNP) | VAF 44/287 reads (15%) | catalogued as rs868719892; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-12763T>G | Intron (SNP) | VAF 55/364 reads (15%) | catalogued as COSV101045270; called by muse, mutect2, varscan2
- SPTBN2 | c.6940-140G>A | Intron (SNP) | VAF 52/349 reads (15%) | catalogued as rs763767644; called by muse, mutect2, varscan2
- TMEM191C | c.296+101C>G | Intron (SNP) | VAF 24/85 reads (28%) | called by muse, mutect2, varscan2
- ZNF717 | chr3:75732105 T>C | 3'Flank (SNP) | VAF 44/293 reads (15%) | catalogued as rs1376048480; called by muse, mutect2, varscan2
